TCGA case TCGA-LG-A9QD — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Hartford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/948a9bbc-60b0-4fb7-a707-76bc41294217

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 68.4 years (24,969 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 366 days (1.0 years).
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib; Days to treatment start: 61 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 130 days; Disease response: With Tumor.
- Days to follow up: 366 days (1.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- Albumin 2.9 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.4; Blood test normal range upper: 4.8].
- Platelets 320 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.5].
- Total Bilirubin 0.5 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.2].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 74 kg; Height: 168 cm; BMI: 26.2.

Family history
- Relatives with cancer history count: 3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LG-A9QD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,580 mg.
  Slide TCGA-LG-A9QD-01A-01-TSA: Section location: Top; Percent tumor cells: 96; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 3; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-LG-A9QD-01A-02-TSB: Section location: Top; Percent tumor cells: 97; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 2; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-LG-A9QD-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LG-A9QD-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; Hepatic inflammation adj tissue: Mild; New tumor event diagnosis indicator: No.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: Sorafinib ( Nexavar).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 366 days; disease-specific survival: no event (censored), 366 days; disease-free interval: no event (censored), 366 days; progression-free interval: no event (censored), 366 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-LG-A9QD-01A-11D-A381-01): tumor purity 0.57, ploidy 2.15, whole-genome doublings 0.
